Somatic mutation profile of tumor specimen TCGA-75-5125-01A (aliquot TCGA-75-5125-01A-01D-1753-08) from TCGA case TCGA-75-5125, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-75-5125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ced268a-0c3c-4204-bf7b-d6ed35fb9423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-5125-10A (Blood Derived Normal), aliquot TCGA-75-5125-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f835c7f5-8be9-4a5d-a07d-df568a883dac

The open-access MAF lists 176 somatic variants for this specimen: 134 protein-altering or splice-affecting, 35 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 35, Nonsense Mutation 6, Splice Site 5, Frame Shift Ins 4, Frame Shift Del 4, RNA 4, Splice Region 3, In Frame Del 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM132E | c.1259G>A p.R420Q (on ENST00000321639; = p.R510Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs139895222, CM150212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.1832T>A p.V611E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56642210; called by muse, mutect2, varscan2
- ACACB | c.4821C>T p.I1607= | Splice Region (SNP) | VAF 14/63 reads (22%) | catalogued as rs776234149, COSV58128696; called by muse, mutect2, varscan2
- ACKR3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.726); catalogued as rs535014620, COSV56020630; called by muse, mutect2, varscan2
- ACTN2 | c.664C>A p.H222N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as COSV63972366; called by muse, mutect2, varscan2
- ADAD1 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV56641769, COSV56643052; called by muse, mutect2, varscan2
- ADCY2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs866989574, COSV57857225, COSV57893995; called by muse, mutect2
- ADD3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs914623953, COSV53320405; called by muse, mutect2, varscan2
- ADGRL4 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100876515; called by muse, mutect2
- AHR | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV54121769, COSV54126985; called by muse, mutect2, varscan2
- AHR | c.2265G>C p.Q755H | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV54121786; called by muse, mutect2, varscan2
- ANK2 | c.3532del p.Q1178Rfs*17 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | catalogued as COSV52157526; called by mutect2, pindel, varscan2
- ANKLE2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV61707950; called by muse, mutect2, varscan2
- ANKRD1 | c.116T>C p.L39S | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV63310903; called by muse, mutect2, varscan2
- ATP11C | c.2560A>T p.K854* | Nonsense Mutation (SNP) | VAF 129/208 reads (62%) | catalogued as COSV59560040; called by muse, mutect2, varscan2
- BOD1L1 | c.3254G>T p.G1085V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV50006951; called by muse, mutect2, varscan2
- BPIFB2 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV50063195; called by muse, mutect2
- CACNA1S | c.1685_1686insC p.L563Afs*24 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | catalogued as COSV100755350; called by mutect2, pindel, varscan2
- CAD | c.6139G>A p.D2047N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV53024031; called by muse, mutect2, varscan2
- CEMIP2 | c.2933G>T p.C978F | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65484290; called by muse, mutect2, varscan2
- CHD4 | c.4766C>T p.S1589L (on ENST00000357008 / NM_001363606.2; = p.S1602L on NM_001273.5) | Missense Mutation (SNP) | VAF 89/299 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs771561972, COSV58896982; called by muse, mutect2, varscan2
- CHD4 | c.4765T>C p.S1589P (on ENST00000357008 / NM_001363606.2; = p.S1602P on NM_001273.5) | Missense Mutation (SNP) | VAF 87/297 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58897001; called by muse, mutect2, varscan2
- CHL1 | c.3368C>A p.P1123Q (on ENST00000397491 / NM_001253387.1; = p.P1139Q on NM_006614.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as COSV56587264; called by muse, mutect2, varscan2
- CLDN25 | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101493615; called by muse, mutect2, varscan2
- CLU | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV57065819; called by muse, mutect2, varscan2
- CNOT3 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55360461; called by muse, mutect2, varscan2
- CPT1C | c.578T>A p.I193N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV54917748; called by muse, mutect2
- CRYBB2 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101236768, COSV101236770, COSV68005498; called by muse, mutect2, varscan2
- CSMD3 | c.8363G>A p.G2788E (on ENST00000297405 / NM_001363185.1; = p.G2619E on NM_052900.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1159461244, COSV52110663; called by muse, mutect2, varscan2
- CYP2C9 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV53246791, COSV53249993; called by muse, mutect2, varscan2
- DENND4C | c.3365T>C p.M1122T (on ENST00000434457 / NM_001330640.2; = p.M1073T on NM_017925.7) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV63008408; called by muse, mutect2, varscan2
- DGKK | c.1413C>A p.G471= | Splice Region (SNP) | VAF 8/10 reads (80%) | catalogued as COSV65706535; called by muse, mutect2, varscan2
- DPH6 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs1011898386, COSV56612815; called by muse, mutect2, varscan2
- DZIP3 | c.2942C>T p.T981I | Missense Mutation (SNP) | VAF 122/267 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV64311235; called by muse, mutect2, varscan2
- EP400 | c.2036G>C p.G679A | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.006); catalogued as rs1205410290, COSV57763973; called by muse, mutect2, varscan2
- FABP12 | c.207A>C p.E69D | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100846584; called by muse, mutect2, varscan2
- FAM174A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV57062006, COSV57063897; called by muse, mutect2
- FAM47B | c.1870C>G p.P624A | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV61452622, COSV61455998; called by muse, mutect2
- FANCM | c.4414G>C p.E1472Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.852); catalogued as COSV57497616; called by muse, mutect2, varscan2
- FBXO42 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV65044584; called by muse, mutect2
- FPGT-TNNI3K | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58546673; called by muse, mutect2, varscan2
- GALE | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV52525185; called by muse, mutect2, varscan2
- GMPPA | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV100354856; called by muse, mutect2
- GRIA3 | c.214A>G p.N72D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.139); catalogued as COSV52050333; called by muse, mutect2
- GRK2 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419740; called by muse, mutect2, varscan2
- GRK2 | c.826+1G>A p.X276_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100419742; called by muse, mutect2, varscan2
- GRK4 | c.590G>C p.G197A (on ENST00000398052 / NM_182982.3; = p.G165A on NM_005307.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61668151; called by muse, mutect2
- HYOU1 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68215201; called by muse, mutect2
- ITGA8 | c.701C>G p.A234G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.823); catalogued as COSV65225166, COSV65236392; called by muse, mutect2, varscan2
- ITIH2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64432084; called by muse, mutect2, varscan2
- JAKMIP2 | c.1889C>A p.P630H | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV54598215; called by muse, mutect2, varscan2
- KALRN | c.2862G>C p.Q954H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53754172; called by muse, mutect2, varscan2
- KDSR | c.789C>G p.F263L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58506034; called by muse, mutect2
- LAMB3 | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs765817202, COSV61915514; called by muse, mutect2, varscan2
- LAMP5 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV55715177; called by muse, mutect2, varscan2
- LEMD3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.431); catalogued as COSV57648625; called by muse, mutect2, varscan2
- LPIN2 | c.2206C>A p.R736S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55237550; called by muse, mutect2, varscan2
- LRRC66 | c.2488C>G p.L830V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV58632204; called by muse, mutect2, varscan2
- LUC7L | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 175/744 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs749623104, COSV53456953; called by muse, mutect2, varscan2
- MAGEC2 | c.327G>C p.W109C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); catalogued as COSV55997802, COSV55997939; called by muse, mutect2
- MAP3K4 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV62330359; called by muse, mutect2, varscan2
- MCTP2 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770399605, COSV63291834; called by muse, mutect2, varscan2
- MDH2 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs145477708, COSV59885295; called by muse, mutect2, varscan2
- MFAP3 | c.167C>G p.S56W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV100491732; called by muse, mutect2
- MGAT1 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | PolyPhen probably damaging (0.985); catalogued as COSV57133114; called by muse, mutect2, varscan2
- MLLT3 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV63494840; called by muse, varscan2
- MMP25 | c.1007-1G>A p.X336_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100339605; called by muse, mutect2, varscan2
- MPO | c.833G>C p.G278A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV56561578; called by muse, mutect2, varscan2
- MS4A4A | c.637A>T p.T213S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59700131; called by muse, mutect2, varscan2
- MUC16 | c.42911T>A p.V14304E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); catalogued as COSV66690080; called by muse, mutect2, varscan2
- MUC7 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as COSV59217163, COSV59218260; called by muse, mutect2, varscan2
- MYD88 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as COSV57170722; called by muse, mutect2, varscan2
- MYF5 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV57354345, COSV57354486, COSV57354743; called by muse, mutect2, varscan2
- NCAPD3 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV73257912; called by muse, mutect2, varscan2
- NLRP9 | c.913T>A p.S305T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV100242767, COSV60460143; called by muse, mutect2, varscan2
- NTRK3 | c.2317C>A p.Q773K (on ENST00000360948 / NM_001012338.2; = p.Q759K on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV62296697, COSV62305605; called by muse, mutect2, varscan2
- OPRM1 | c.1022T>A p.L341Q | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57672888; called by muse, mutect2, varscan2
- OR11H1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99421985; called by mutect2, varscan2
- OR4C12 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100078660; called by muse, mutect2, varscan2
- OR4C12 | c.499T>C p.C167R | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100078665; called by muse, mutect2, varscan2
- OR52E6 | c.359T>A p.M120K | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100259538; called by muse, mutect2, varscan2
- OTUD4 | c.2831G>A p.R944Q (on ENST00000447906 / NM_001366057.1; = p.R879Q on NM_001102653.1) | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs199938948; called by muse, mutect2, varscan2
- P4HB | c.1356G>C p.R452S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV58940083; called by muse, mutect2, varscan2
- PCDH1 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746902; called by muse, mutect2
- PCDHA7 | c.1756G>T p.G586C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); catalogued as rs782727190, COSV65342112; called by muse, mutect2, varscan2
- PDGFRA | c.1301G>C p.R434T | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.076); catalogued as COSV57264700, COSV57265128; called by muse, mutect2, varscan2
- PHOX2B | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.172); catalogued as rs1260084723, COSV56928585, COSV56930950; called by muse, mutect2
- PIKFYVE | c.4115C>G p.S1372C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52237479; called by muse, mutect2, varscan2
- PITHD1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV99862228; called by muse, mutect2, varscan2
- PLAUR | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99655396; called by muse, mutect2
- POF1B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs150903638, COSV53130682; called by muse, mutect2, varscan2
- POLM | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV54241500; called by muse, mutect2, varscan2
- POU3F4 | c.296C>A p.P99Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV64537891; called by muse, mutect2, varscan2
- PSMB11 | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs755271648, COSV57458713, COSV57459122; called by muse, mutect2, varscan2
- PSME4 | c.3341C>A p.S1114Y | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV66363346, COSV66364687; called by muse, mutect2
- RIMS2 | c.4292G>T p.R1431L (on ENST00000666250 / NM_001348490.2; = p.R1002L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655841, COSV51695249; called by muse, mutect2, varscan2
- RPA4 | c.501G>T p.M167I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100235111; called by muse, mutect2, varscan2
- RPIA | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52168247; called by muse, mutect2, varscan2
- RPSA | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV57191003; called by muse, mutect2, varscan2
- SEMA6B | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.658); catalogued as rs1179507289, COSV56702474; called by muse, mutect2, varscan2
- SESTD1 | c.1962-1G>C p.X654_splice | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100090865; called by muse, mutect2, varscan2
- SF1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV57111728; called by muse, mutect2, varscan2
- SLC1A1 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs1247856099, COSV52050003; called by muse, mutect2
- SRGAP1 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1241454988, COSV61894796; called by muse, mutect2, varscan2
- TAGAP | c.1136C>G p.P379R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57850595; called by muse, mutect2, varscan2
- TECTA | c.5662A>G p.R1888G | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50689148; called by muse, mutect2, varscan2
- TFEC | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55397863; called by muse, mutect2, varscan2
- TIMD4 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV50854054; called by muse, mutect2
- TRAM1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775493429, COSV51596775; called by muse, mutect2, varscan2
- TRNT1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180975633, COSV51639962; called by muse, mutect2
- UBR2 | c.3084A>C p.K1028N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV65748945; called by muse, mutect2
- VPS13B | c.4041A>G p.T1347= | Splice Region (SNP) | VAF 11/142 reads (8%) | catalogued as COSV62134255; called by muse, mutect2
- VWF | c.3580G>A p.E1194K | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1389202589, COSV54612630; called by muse, mutect2, varscan2
- WTAP | c.635A>C p.D212A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV64329686; called by muse, mutect2
- XRCC6 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV63158506; called by muse, mutect2, varscan2
- ZBTB8OS | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV59384814; called by muse, mutect2
- ZC2HC1C | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV53172065; called by muse, mutect2
- ZNF248 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV61997190; called by muse, mutect2, varscan2
- ZNF282 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50479137; called by muse, mutect2
- ZNF431 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100219035, COSV60675175; called by muse, mutect2, varscan2
- ZNF431 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100219039; called by muse, mutect2, varscan2
- ZNF831 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770965970, COSV64037750; called by muse, mutect2, varscan2
- ZNF835 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73379205; called by muse, mutect2, varscan2
- AF196969.1 | c.216_217dup p.G73Vfs*7 | Frame Shift Ins (INS) | VAF 27/49 reads (55%) | called by mutect2, varscan2
- ARMC1 | c.589_591del p.A197del | In Frame Del (DEL) | VAF 33/122 reads (27%) | called by mutect2, pindel, varscan2
- DEPTOR | c.926-1del p.X309_splice | Splice Site (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel*, varscan2
- DERL1 | c.507-13_519del p.X169_splice | Splice Site (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel
- ELMO2 | c.261del p.Q87Hfs*2 | Frame Shift Del (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel*, varscan2
- GIMAP6 | c.261dup p.G88Wfs*5 | Frame Shift Ins (INS) | VAF 53/171 reads (31%) | called by mutect2, pindel, varscan2
- MUC16 | c.8647dup p.W2883Lfs*11 | Frame Shift Ins (INS) | VAF 4/19 reads (21%) | called by mutect2, pindel
- RPL6 | c.861_865del p.F288Nfs*6 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- SPTLC3 | c.51_56del p.H17_K19delinsQ | In Frame Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- TCEAL5 | c.369del p.T124Rfs*17 | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | called by mutect2, pindel, varscan2
- AMER1 | c.1332T>A p.S444= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100366091, COSV57655490; called by muse, mutect2, varscan2
- AMER3 | c.564G>A p.G188= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs777251443, COSV58465312; called by muse, mutect2
- ANKRD17 | c.6660A>G p.L2220= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as rs1246930828, COSV58215920; called by muse, mutect2, varscan2
- B4GALNT1 | c.832C>T p.L278= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57541471; called by muse, mutect2, varscan2
- BRINP1 | c.1950C>T p.I650= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as COSV56292915; called by muse, mutect2, varscan2
- CIT | c.5145C>T p.Y1715= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1465701956, COSV55861078; called by muse, mutect2, varscan2
- CRYBB2 | c.435G>T p.R145= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101236771; called by muse, mutect2, varscan2
- DNAI3 | c.1221G>A p.P407= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as rs139599532, COSV54000829; called by muse, mutect2
- FIGNL1 | c.1944T>C p.F648= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs746239007, COSV63553233; called by muse, mutect2, varscan2
- FLRT2 | c.1050C>G p.V350= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100419901, COSV58136888; called by muse, mutect2, varscan2
- GPR182 | c.39G>A p.E13= | Silent (SNP) | VAF 49/149 reads (33%) | catalogued as rs375649204; called by muse, mutect2, varscan2
- HPSE | c.1498C>T p.L500= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV60985599; called by muse, mutect2, varscan2
- IL9R | c.411G>T p.P137= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54898405; called by muse, mutect2, varscan2
- KIAA1109 | c.12144A>T p.R4048= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV52663336; called by muse, mutect2, varscan2
- LILRB1 | c.1584C>A p.L528= (on ENST00000427581; = p.L478= on NM_006669.6) | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV61116182; called by muse, mutect2
- MTFMT | c.747T>C p.S249= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs1477794472, COSV54977072; called by muse, mutect2, varscan2
- NALCN | c.2673C>A p.V891= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV51919983; called by muse, mutect2, varscan2
- NCAM1 | c.369G>A p.A123= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs541244567, COSV57511190; called by muse, mutect2, varscan2
- NDC80 | c.1860G>A p.S620= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs772517003, COSV55247040, COSV55247417; called by muse, mutect2
- OPTC | c.129T>C p.V43= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV58115024; called by muse, mutect2, varscan2
- OR4C11 | c.720T>A p.S240= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV56352279; called by muse, mutect2, varscan2
- OR9G4 | c.273C>G p.R91= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV57247807, COSV57249481; called by muse, mutect2, varscan2
- PCDHGB1 | c.1914G>T p.L638= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs762320091, COSV53905116; called by muse, varscan2
- PCLO | c.9531G>T p.T3177= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV61617696, COSV61647827; called by muse, mutect2, varscan2
- PIK3C2G | c.1800T>A p.T600= (on ENST00000676171; = p.T559= on NM_004570.5) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV56798315; called by muse, mutect2
- POLL | c.1665T>C p.T555= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100150448; called by muse, mutect2, varscan2
- PRKAG2 | c.573C>A p.I191= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV55222523; called by muse, mutect2, varscan2
- PTK6 | c.690G>A p.Q230= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as rs1291378733, COSV53915984; called by muse, mutect2
- RELN | c.2352G>T p.T784= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV58987333; called by muse, mutect2, varscan2
- SEMA6D | c.1677C>T p.F559= (on ENST00000316364 / NM_153618.2; = p.F572= on NM_020858.2) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs375100072; called by muse, mutect2, varscan2
- SMG5 | c.756C>G p.L252= | Silent (SNP) | VAF 11/245 reads (4%) | catalogued as COSV62434082, COSV62434971; called by muse, mutect2
- SON | c.5370T>C p.Y1790= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV51651567; called by muse, mutect2, varscan2
- TERT | c.2250C>T p.A750= | Silent (SNP) | VAF 175/493 reads (35%) | catalogued as rs941567959, COSV57201130; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNRC6A | c.4851A>G p.P1617= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV59361616; called by muse, mutect2, varscan2
- VCAN | c.5478T>C p.R1826= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV54097814; called by muse, mutect2, varscan2
- CPLANE1 | c.*4642C>T | 3'UTR (SNP) | VAF 10/83 reads (12%) | catalogued as COSV57053300, COSV57060927; called by muse, mutect2, varscan2
- DCHS2 | n.1113C>G | RNA (SNP) | VAF 27/79 reads (34%) | catalogued as COSV59719082; called by muse, mutect2, varscan2
- LIM2 | c.175+10C>A | Intron (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99702467; called by muse, mutect2, varscan2
- MIR518A1 | n.14C>A | RNA (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- MORF4 | n.568T>A | RNA (SNP) | VAF 109/324 reads (34%) | called by muse, mutect2, varscan2
- PRB1 | c.101-1537G>T | Intron (SNP) | VAF 14/116 reads (12%) | catalogued as COSV53702617; called by muse, mutect2, varscan2
- TCP10L3 | n.473G>A | RNA (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100833258; called by muse, mutect2, varscan2
